Somatic mutation profile of tumor specimen MP2PRT-PARDKM-TMP1-A (aliquot MP2PRT-PARDKM-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARDKM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,721 days).
Specimen MP2PRT-PARDKM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68224d8c-3c51-4d16-8898-c7d78a5dddff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARDKM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARDKM-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0330781-40fa-4c98-abf2-052dae3accb6

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1862A>T p.N621I (on ENST00000288602 / NM_001374244.1; = p.N581I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV56058108, COSV56106422, COSV56110832; called by muse, mutect2, varscan2
- CALN1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 62/420 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs1393529730, COSV67945448; called by muse, mutect2, varscan2
- MS4A6A | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs1429565678; called by muse, mutect2, varscan2
- ADGRG4 | c.1563G>C p.R521S | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- NIPBL | c.6504C>A p.N2168K | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- AFF3 | c.1833G>A p.A611= | Silent (SNP) | VAF 232/565 reads (41%) | called by muse, mutect2, varscan2
- HK2 | c.963G>A p.G321= | Silent (SNP) | VAF 123/324 reads (38%) | called by muse, mutect2, varscan2
- ZFAND4 | c.801A>G p.R267= | Silent (SNP) | VAF 140/363 reads (39%) | called by muse, mutect2, varscan2
- DENND1B | c.83-20694T>C | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
